Somatic mutation profile of tumor specimen MP2PRT-PAWAHB-TMP1-A (aliquot MP2PRT-PAWAHB-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWAHB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,102 days).
Specimen MP2PRT-PAWAHB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6697f766-c10d-4b6b-8d4f-117bd6e20ebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAHB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAHB-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59805f32-4daf-4bd7-b6b9-99f11dfc24cd

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Nonsense Mutation 2, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 115/259 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD62 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 85/183 reads (46%) | catalogued as rs1048611767; called by muse, mutect2, varscan2
- ARMC4 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 121/301 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV59470660; called by muse, mutect2, varscan2
- ARMC9 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 217/459 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1299878585; called by muse, mutect2, varscan2
- CACNA2D4 | c.1564C>T p.R522* | Nonsense Mutation (SNP) | VAF 98/260 reads (38%) | catalogued as rs572396211; called by muse, mutect2, varscan2
- CFAP46 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 179/422 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1197857517, COSV63955483; called by muse, mutect2, varscan2
- CHD7 | c.6366A>T p.L2122F | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as COSV71112066; called by muse, mutect2, varscan2
- DOCK4 | c.4202C>T p.P1401L | Missense Mutation (SNP) | VAF 128/289 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755794179, COSV70239686; called by muse, mutect2, varscan2
- EFCAB6 | c.4369G>A p.A1457T | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as rs751667777; called by muse, mutect2, varscan2
- FRAT1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1254324904; called by muse, mutect2, varscan2
- HECTD4 | c.3077C>T p.P1026L | Missense Mutation (SNP) | VAF 147/336 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs774386728, COSV61177756, COSV61181821; called by muse, mutect2, varscan2
- MPP6 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554315658; called by muse, mutect2, varscan2
- NTRK3 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs546426782, COSV100446296, COSV58125477; called by muse, mutect2, varscan2
- SCEL | c.896G>A p.R299Q (on ENST00000349847 / NM_144777.3; = p.R279Q on NM_003843.4) | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.029); catalogued as rs149394221; called by muse, mutect2, varscan2
- SLC39A12 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs546207056, COSV66199857; called by muse, mutect2, varscan2
- VIT | c.919C>T p.R307W (on ENST00000389975 / NM_001177969.1; = p.R322W on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748465900, COSV64899029; called by muse, mutect2, varscan2
- ABCD2 | c.58_59insGCT p.A20delinsGS | In Frame Ins (INS) | VAF 120/325 reads (37%) | called by mutect2, pindel, varscan2
- ART3 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ELAVL2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 196/470 reads (42%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- EVPLL | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 126/365 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GJA1 | c.245T>C p.I82T | Missense Mutation (SNP) | VAF 149/302 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- HECTD4 | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PAEP | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- PCSK5 | c.3667G>T p.V1223L | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RNF186 | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THSD7B | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TLL1 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF571 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 125/275 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- AFF1 | c.1719C>T p.A573= | Silent (SNP) | VAF 137/255 reads (54%) | called by muse, mutect2, varscan2
- ARHGEF38 | c.294C>T p.I98= | Silent (SNP) | VAF 87/234 reads (37%) | catalogued as rs1056064658; called by muse, mutect2, varscan2
- BCL11B | c.1743C>T p.G581= (on ENST00000357195 / NM_001282237.2; = p.G510= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 388/844 reads (46%) | catalogued as rs1334065341, COSV61734688; called by muse, mutect2, varscan2
- GJA8 | c.372G>A p.P124= | Silent (SNP) | VAF 152/319 reads (48%) | catalogued as rs782036781, COSV53789149, COSV53790561; called by muse, mutect2, varscan2
- HTR1A | c.969G>A p.R323= | Silent (SNP) | VAF 184/390 reads (47%) | catalogued as COSV60499908; called by muse, mutect2, varscan2
- JAK1 | c.447C>T p.L149= | Silent (SNP) | VAF 97/206 reads (47%) | called by muse, mutect2, varscan2
- OR10G2 | c.24G>A p.S8= | Silent (SNP) | VAF 113/426 reads (27%) | catalogued as rs760864904; called by muse, mutect2, varscan2
- C6orf52 | c.317-1000C>T | Intron (SNP) | VAF 131/282 reads (46%) | called by muse, mutect2, varscan2
